Surgical pathology report (de-identified scan), TCGA case TCGA-66-2757, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2757-01A (Primary Tumor).

[page 1 of 2]
Examination report

Macroscopic findings:

1. (a-f) Left upper lobe of lung: resected lung tissue weighing 232g, and measuring 190 x 120 x 40 mm, with anthracosis of the pleura. Located in the peripheral section of S 1 up to the segmental bronchi there is a polycyclic and well demarcated, grayish-white, hyaline, tumorous node measuring max 28 mm, without pleural infiltration. The peritumoral section has a significantly coarsened edge with an indication of a honeycomb structure. In the hilar section there are small, lymph nodes with blackish pigment but without any suspicion of a tumor. No further pulmonary findings.
2. L 12: Torn, node measuring a good 10 mm, with blackish pigment.
3. L 11: 6 mm node with blackish pigment.
4. L10: Grayish-black lymph node tissue measuring 20 mm in total.
5. L 9: Grayish-white node measuring 5 mm with blackish pigment.
6. L 8: Piece of tissue measuring 4 mm with blackish pigment.
7. L 7: Node measuring just under 10 mm with blackish pigment.
8. L 6: Node measuring 12 mm with blackish pigment.
9. L 5: Node measuring 7 mm with blackish pigment.
10. L 4: Nodule measuring 2 mm with blackish pigment.

Microscopic findings:

1. (HE, PAS, EvG) The bronchial resection margin is tumor-free with regular architecture. Next to this, in the hilar and peribronchial area, there are tumor-free lymph nodes with significant anthracosis and slight histiocytosis. The tumor described is made up of solid, growing structures of immature squamous cell carcinoma cells with fusocellular morphology with a significantly misaligned nucleoplasmic ratio and frequent mitosis, and with a very sparse and narrow cytoplasmic border. No keratinizing growth. Necrosis included, alongside stromal desmoplasia. In the area of an embedded subsegmental bronchus there is subepithelial, intramural tumor propagation. Apart from the tumor, unremarkable pulmonary parenchyma.
2. (HE) Torn lymph node tissue with haemorrhaging and moderate histiocytosis as well as anthracosis. No indication of tumor.
3. (HE) Similar findings to 2
4. (HE) Similar findings to 2
5. (HE) Similar findings to 2
6. (HE) Similar findings to 2
7. (HE) Similar findings to 2
8. (HE) Similar findings to 2
9. (HE) Similar findings to 2
10. (HE) Similar findings to 2

[page 2 of 2]
Diagnosis: Resected left superior pulmonary lobe with a badly differentiated and non-keratinizing squamous cell carcinoma in S 1, measuring 28 mm, with subepithelial, intramural infiltration of a subsegmental bronchus from B1, without pleural infiltration or discernible hemangioinvasion with tumor-free lymph nodes containing anthracotic pigment.

2. to 10. Further tumor-free lymph nodes, containing anthracotic pigment.

Tumor classification: M-8070/3, G 3, pT 1, pN 0, pMX, stage I A. R0.

Left upper lobe of lung

Lymph nodes

Source: NCI Genomic Data Commons file 14b5e405-601e-4441-8980-23249d72a5d3 (TCGA-66-2757.B44205A6-8C17-4B6B-BB91-EC1AD1BE0B3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).